Gene-level copy-number profile of tumor specimen C3N-08883-01 (profiled together with C3N-08883-02, C3N-08883-03) from CPTAC case C3N-08883, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.0 years (23,359 days).
Specimen C3N-08883-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 589e9b95-9043-4848-9825-affe3b46a826.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-08883-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,746 have no estimate.
https://portal.gdc.cancer.gov/files/55b474aa-8069-4455-8edc-7de898164373

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,808; copy number 3: 16; copy number 4: 46,049; copy number 5: 9,700; copy number 6: 54; copy number 7: 23; copy number 8: 73; copy number 9: 39; copy number 10: 11; copy number 11: 49; copy number 12: 8; copy number 15: 9; copy number 20: 12; copy number 22: 19; copy number 24: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 154 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:10,525,532–12,115,516, 59 genes, copy number 9–11 (within-gene range 8–11): PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1, AF131215.7, LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D.
- chr8:12,310,962–12,333,693, 2 genes, copy number 10: DEFB130A, RNA5SP254.
- chr8:30,095,408–30,201,332, 8 genes, copy number 11: LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3.
- chr12:24,949,163–26,938,326, 43 genes, copy number 12–24 (within-gene range 7–24): AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13.
- chr13:33,818,069–33,966,558, 1 gene, copy number 11 (within-gene range 8–11): RFC3.
- chr13:34,079,411–36,131,382, 17 genes, copy number 9–11: AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1.
- chr13:41,517,168–41,961,120, 2 genes, copy number 9 (within-gene range 5–9): AL354833.1, VWA8.
- chr13:41,807,677–43,181,193, 22 genes, copy number 9–22: RN7SL515P, RNU6-74P, KARS1P1, VWA8-AS1, RPS28P8, DGKH, AL157932.1, MAPK6P3, CHCHD2P11, FHP1, AKAP11, LINC02341, FABP3P2, TNFSF11, FAM216B, LINC01050, LINC00428, EPSTI1, ZDHHC4P1, DNAJC15, LINC00400, AL138709.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
